Gene-level copy-number profile of tumor specimen C3L-01160-01 from CPTAC case C3L-01160, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.3 years (22,041 days).
Specimen C3L-01160-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a7b2641-26c2-44d6-8b08-4d109870150f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01160-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/37671493-72a9-4468-8475-40e6e5458360

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,558; copy number 3: 166; copy number 4: 42,612; copy number 5: 3,356; copy number 6: 3,855; copy number 7: 1,515; copy number 8: 1; copy number 9: 880; copy number 12: 373; copy number 13: 5; copy number 15: 11; copy number 16: 13; copy number 21: 9; copy number 24: 43; copy number 28: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,335 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:12,310–34,249,958, 834 genes, copy number 9 (broad region; genes not listed).
- chr12:39,293,228–39,619,803, 5 genes, copy number 9: KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3.
- chr18:45,034–15,330,282, 367 genes, copy number 12 (broad region; genes not listed).
- chr18:21,240,675–25,056,760, 89 genes, copy number 9–24 (broad region; genes not listed).
- chr18:25,818,234–28,789,580, 40 genes, copy number 9–28: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
